Somatic mutation profile of tumor specimen TCGA-SX-A71W-01A (aliquot TCGA-SX-A71W-01A-12D-A34Z-10) from TCGA case TCGA-SX-A71W, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.0 years (24,110 days).
Specimen TCGA-SX-A71W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75be999e-df2f-4f99-bf7f-24b8ca4e03b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A71W-10A (Blood Derived Normal), aliquot TCGA-SX-A71W-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92669b64-ea67-42ce-979b-6041fec2fae0

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Frame Shift Del 3, Nonsense Mutation 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF25 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs766237649, COSV99678370; called by muse, mutect2, varscan2
- ARIH1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101158927; called by muse, mutect2, varscan2
- CNDP2 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60840623; called by muse, mutect2, varscan2
- COL15A1 | c.2621T>C p.L874P | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100898053; called by muse, mutect2, varscan2
- FBXO46 | c.98A>C p.K33T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as COSV100480465; called by muse, varscan2
- FBXO46 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.067); catalogued as COSV100480468; called by muse, varscan2
- GAA | c.1754+2T>G p.X585_splice | Splice Site (SNP) | VAF 18/27 reads (67%) | catalogued as CS120517, COSV100163581; called by muse, mutect2, varscan2
- GCNT2 | c.798C>G p.Y266* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV101097726; called by muse, mutect2, varscan2
- GNE | c.566T>C p.V189A (on ENST00000396594 / NM_001128227.3; = p.V158A on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100930159; called by muse, mutect2, varscan2
- GPR148 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99998780; called by muse, mutect2, varscan2
- GRIP1 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 78/123 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99671277; called by muse, mutect2, varscan2
- HK1 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100068174; called by muse, mutect2, varscan2
- HUWE1 | c.11789C>T p.S3930F | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV99474642; called by muse, mutect2, varscan2
- INO80C | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as rs1389740271, COSV99358574; called by muse, mutect2
- IRF2BP1 | c.1498C>G p.P500A | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100139040; called by muse, mutect2, varscan2
- IRF2BPL | c.56T>A p.L19Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99468548; called by muse, mutect2, varscan2
- KIAA0232 | c.3769G>T p.D1257Y | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100301150; called by muse, mutect2, varscan2
- LRRK2 | c.6218T>C p.I2073T | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as COSV100111328; called by muse, mutect2, varscan2
- PKP3 | c.2230G>A p.G744R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201401216, COSV58987148; called by muse, mutect2, varscan2
- RUNDC1 | c.1826T>C p.I609T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100865902; called by muse, mutect2
- SGO2 | c.1416A>T p.K472N | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV100764820; called by muse, mutect2, varscan2
- SH3BP5 | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV99508643; called by muse, mutect2, varscan2
- SPAG11B | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs780854740, COSV52500527, COSV99873302; called by muse, mutect2, varscan2
- UGT1A4 | c.458C>G p.P153R | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100531210; called by muse, mutect2, varscan2
- ZBTB5 | c.362C>A p.T121K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57041153; called by muse, mutect2, varscan2
- HHIPL1 | c.610del p.D204Mfs*30 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by pindel, varscan2
- UNC79 | c.3086del p.P1029Lfs*20 (on ENST00000393151 / NM_001346218.2; = p.P852Lfs*20 on NM_020818.5) | Frame Shift Del (DEL) | VAF 77/219 reads (35%) | called by mutect2, pindel, varscan2
- UNC79 | c.6623del p.P2208Lfs*20 (on ENST00000393151 / NM_001346218.2; = p.P2031Lfs*20 on NM_020818.5) | Frame Shift Del (DEL) | VAF 27/83 reads (33%) | called by mutect2, pindel, varscan2
- ALB | c.774A>G p.L258= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99892447; called by muse, mutect2, varscan2
- CFTR | c.2125C>A p.R709= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as CM950248, COSV50041819, COSV99140454; called by muse, mutect2, varscan2
- ERP27 | c.522G>A p.E174= | Silent (SNP) | VAF 79/149 reads (53%) | catalogued as COSV99844493; called by muse, mutect2, varscan2
- FBXO46 | c.96C>A p.L32= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100480470; called by muse, varscan2
- LRPPRC | c.3237A>G p.S1079= | Silent (SNP) | VAF 76/200 reads (38%) | catalogued as COSV99581604; called by muse, mutect2, varscan2
- MRPS18A | c.240G>A p.K80= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs568509997, COSV100928784; called by muse, mutect2, varscan2
- SIGLEC1 | c.4686C>G p.A1562= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99171445; called by muse, mutect2
- ZNF641 | c.1299A>G p.R433= | Silent (SNP) | VAF 33/47 reads (70%) | catalogued as COSV99973715; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 4/28 reads (14%) | catalogued as rs201441562; called by pindel, varscan2
